Somatic mutation profile of tumor specimen 0DJR16 from CCDI case PBBXMJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Cerebrum; Age at diagnosis: 14.9 years (5,427 days).
Specimen 0DJR16: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d10bd8f8-19a9-47cb-9f2c-107cd6d61d0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJQZK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe4b40f9-6fcc-496e-a91a-fb726679e78e

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 4, Intron 2, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 174/516 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.715A>G p.N239D | Missense Mutation (SNP) | VAF 195/558 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs876660807, COSV52664075, COSV52685174, COSV52979974, COSV53345856; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 146/462 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- AGAP2 | c.2092A>T p.K698* (on ENST00000547588 / NM_001122772.2; = p.K362* on NM_014770.4) | Nonsense Mutation (SNP) | VAF 2258/2744 reads (82%) | catalogued as rs1555198739; called by muse, mutect2, varscan2
- CCDC142 | c.1661G>A p.R554H (on ENST00000393965 / NM_001365575.2; = p.R547H on NM_032779.4) | Missense Mutation (SNP) | VAF 264/817 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.425); catalogued as rs778843760; called by muse, mutect2, varscan2
- OR3A2 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 405/1175 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.236); catalogued as COSV68694977; called by muse, mutect2, varscan2
- PLCZ1 | c.1102A>G p.R368G | Missense Mutation (SNP) | VAF 50/1778 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV99856973; called by muse, mutect2
- PLSCR1 | c.34C>T p.H12Y | Missense Mutation (SNP) | VAF 352/1117 reads (32%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as rs754864062, COSV61013134; called by muse, mutect2, varscan2
- SLC37A1 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 82/374 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as rs375464840; called by muse, mutect2, varscan2
- TAGAP | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 57/744 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV57852692; called by muse, mutect2
- ARHGEF25 | c.682T>C p.C228R | Missense Mutation (SNP) | VAF 131/5010 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2
- CDK19 | c.467A>G p.N156S | Missense Mutation (SNP) | VAF 187/688 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCGBP | c.3299G>A p.G1100D | Missense Mutation (SNP) | VAF 82/294 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNV1 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 40/879 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.092); called by muse, mutect2
- LIN54 | c.2102T>A p.L701H | Missense Mutation (SNP) | VAF 61/1359 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PGBD4 | c.1256G>T p.R419L | Missense Mutation (SNP) | VAF 183/573 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF469 | c.4115C>T p.P1372L (on ENST00000437464; = p.P1400L on NM_001367624.2) | Missense Mutation (SNP) | VAF 148/578 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); called by muse, mutect2
- ZNF517 | c.971A>G p.Q324R | Missense Mutation (SNP) | VAF 244/770 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CCDC40 | c.1545G>A p.A515= | Silent (SNP) | VAF 190/513 reads (37%) | catalogued as rs200526079, COSV53903910; called by muse, mutect2, varscan2
- KRT18 | c.771C>T p.D257= | Silent (SNP) | VAF 80/970 reads (8%) | catalogued as rs529125152; called by muse, mutect2
- MUC16 | c.2493G>A p.S831= | Silent (SNP) | VAF 135/334 reads (40%) | catalogued as rs764383339, COSV67454733; called by muse, mutect2, varscan2
- SLC9B1 | c.237T>C p.C79= | Silent (SNP) | VAF 130/667 reads (19%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 13/332 reads (4%) | called by muse, mutect2
- SIX6 | c.-81del | 5'UTR (DEL) | VAF 3/26 reads (12%) | called by mutect2, varscan2
- TMEFF2 | c.439+41G>C | Intron (SNP) | VAF 159/630 reads (25%) | catalogued as COSV99772043; called by muse, mutect2
